Somatic mutation profile of tumor specimen 0DMIOG from CCDI case PBBUAF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Ethmoid sinus; Age at diagnosis: 12.6 years (4,612 days).
Specimen 0DMIOG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a456d912-45e7-430d-ba04-55d4b75b654e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMIPF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae5cd524-7590-4752-8145-bc5ef9949f88

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 3'UTR 3, Intron 2, Nonsense Mutation 1, Frame Shift Del 1, 5'UTR 1, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GAT1 | c.113-5C>T | Splice Region (SNP) | VAF 57/189 reads (30%) | catalogued as rs1228965058; called by muse, mutect2, varscan2
- CSMD1 | c.5728A>T p.T1910S (on ENST00000520002; = p.T1909S on NM_033225.6) | Missense Mutation (SNP) | VAF 130/578 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV59303381; called by muse, mutect2, varscan2
- EBLN1 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 55/399 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs765282974, COSV69370237; called by muse, mutect2, varscan2
- TPST1 | c.632G>T p.C211F | Missense Mutation (SNP) | VAF 58/462 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59179760; called by muse, mutect2, varscan2
- DSP | c.2356del p.V786Ffs*26 | Frame Shift Del (DEL) | VAF 102/488 reads (21%) | called by mutect2, varscan2
- ERN1 | c.284A>G p.K95R | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 40/992 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- HR | c.845G>T p.C282F | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.018); called by muse, mutect2
- SEC24D | c.369G>T p.Q123H | Missense Mutation (SNP) | VAF 127/600 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SH2B3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- TMEFF2 | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 138/886 reads (16%) | called by muse, varscan2
- OR8J3 | c.285T>C p.Y95= | Silent (SNP) | VAF 104/590 reads (18%) | called by muse, varscan2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 4/36 reads (11%) | called by muse, varscan2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 9/86 reads (10%) | called by muse, varscan2
- HMGB1 | c.*85T>C | 3'UTR (SNP) | VAF 10/174 reads (6%) | catalogued as COSV100360835; called by muse, mutect2
- MUCL1 | c.*83C>T | 3'UTR (SNP) | VAF 35/138 reads (25%) | catalogued as rs1041266979, COSV100446022; called by muse, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 22/178 reads (12%) | called by muse, varscan2
